Surgical pathology report (de-identified scan), TCGA case TCGA-JV-A75J, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-JV-A75J-01A (Primary Tumor).

[page 1 of 4]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Surgical Pathology:

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD O-3
Leiomyosarcoma NOS
8890/3
Site: C&F Uterus NOS C55.9
path Fundus Uteri C54.3
9/28/11/13

PATHOLOGIC DIAGNOSIS

A. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, HYSTERECTOMY WITH
BILATERAL SALPINGO-OOPHORECTOMY:

UTERINE CORPUS:

- UTERINE LEIOMYOSARCOMA
- Tumor site: POSTERIOR UTERINE FUNDUS
- Tumor size: 18 X 18 X 12 CM
- LYMPHOVASCULAR INVASION PRESENT
- TUMOR EXTENDS THROUGH THE UTERINE SEROSA
- Disordered proliferative endometrium
- Leiomyomata

CERVIX:

- NO TUMOR PRESENT

BILATERAL FALLOPIAN TUBES:

- NO TUMOR PRESENT

BILATERAL OVARIES:

- NO TUMOR PRESENT

B. PELVIC TUMOR, EXCISION:

- METASTATIC LEIOMYOSARCOMA

C. OMENTUM, BIOPSY:

- METASTATIC LEIOMYOSARCOMA

D. SMALL BOWEL IMPLANT, BIOPSY:

- METASTATIC LEIOMYOSARCOMA

E. APPENDIX, APPENDECTOMY:

- METASTATIC LEIOMYOSARCOMA IN PERIAPPENDICEAL SOFT TISSUE

F. LYMPH NODES, LEFT PELVIC, DISSECTION:

- TWO LYMPH NODES, NO TUMOR PRESENT (0/2)

G. PELVIC IMPLANT:

- METASTATIC LEIOMYOSARCOMA

PATHOLOGIC STAGING: Stage IIIB

Primary tumor pT3b: Tumor invades abdominal tissue at multiple sites

[page 2 of 4]
Regional lymph nodes pN0: No regional lymph node metastases
Distant metastases (pM): Cannot be assessed

Staff Pathologist

Comment

The tumor shows diffuse marked cytologic atypia, abundant coagulative tumor cell necrosis and mitotic rate of upto 68 mitoses per 10 high power fields.

Intraoperative Consultation

Intraoperative Frozen Section Diagnosis

FSA1: Right adnexal mass:

- High grade sarcoma consistent with leiomyosarcoma
- Verbally reported to

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

History of large adnexal mass.

Gross Description

Specimen Material: A. Uterus, cervix, bilateral tubes and ovaries. B. Pelvic tumor, C. Omentum, D. Small bowel implant, E. Appendix, F. Left pelvic lymph node, G. Pelvic implant. Total abdominal hysterectomy, exploratory laparotomy, bilateral salpingo-oophorectomy, appendectomy, omentectomy, tumor debulking, left pelvic lymph node dissection, right uretectomy.

The case is received in seven parts labeled with the patient's name , medical record number and given accession number , and it is accompanied by a requisition form labeled with the same name and accession number.

Part A: Received fresh for intraoperative consultation labeled "UTERUS, CERVIX, BILATERAL TUBES AND OVARIES" is a 2.12 kilogram mass 18.0 x 18.0 x 12.0 cm which is attached to the posterior fundus of a 7.0 x 7.0 x 5.0 uterus with an attached cervix measuring 1.5 x 2.5 cm, the cervical os measuring 0.5 cm, along with attached bilateral fallopian tubes and ovaries, the left fallopian tube measuring 6.0 x 0.5 cm, the left ovary measuring 2.7 x 1.5 x 0.4 cm, the right fallopian tube measuring 6.0 x 0.4 cm, the right ovary measuring 3.0 x 2.0 x 0.5 cm.

The uterine serosa is tan-pink, smooth. In the region of posterior fundus around the right cornua is a large necrotic and bulging mass with disrupted surface. On sectioning, the mass is variegated, tan-yellow to pink-red fleshy to firm areas, with abundant hemorrhage and necrosis. The endometrium measures 0.2 cm in thickness, the myometrium measures 2.0 cm in thickness. There are multiple tan-white, firm, whorled, intramural nodules ranging in size from 2.0 cm to 1.0 cm in their greatest dimension. Bilateral fallopian tubes and ovaries are unremarkable.

Representative sections are submitted as follows:

FSA1: section of the mass

A2: anterior cervix

A3: full thickness section including endometrium and myometrium

A4: posterior cervix

A5: full thickness section including endometrium and myometrium

[page 3 of 4]
A6: left fallopian tube
A7: left ovary
A8: right fallopian tube
A9: right ovary
A10: tumor to right fallopian tube
A11: tumor to posterior uterine fundus
A12-A24: sections of mass

Part B. Received in formalin labeled "B PELVIC" is a 10 x 8 x 3 cm tan-yellow, rubbery, necrotic and disrupted tissue fragment. Representative sections are submitted in cassettes B1-B5

Part C. Received in formalin labeled "OMENTUM" is a 25 x 12 x 1 cm omentum. The surface is yellow and hemorrhagic, lobulated. No discrete masses are identified. Representative sections are submitted in cassettes C1-C5.

Part D. Received in formalin labeled "SMALL BOWEL" is a 2.0 x 1.8 x 0.6 cm tan-white irregular and unoriented piece of tissue. The specimen is serially sectioned and submitted entirely in cassettes D1 and D2.

Part E. Received in formalin labeled "APPENDIX" is a 7 cm in length and 0.7 cm in diameter appendix with moderate attached mesoappendix. The serosa is pink and hemorrhagic, no exudate or transmural defects are identified. The proximal margin is inked blue. The wall measures 0.5 cm thick, no fecaliths are identified. The specimen is serially sectioned and submitted entirely in five cassettes.

Part F. Received in formalin labeled "LEFT PELVIC LYMPH NODE" is a 3.5 x 2.0 x 0.5 cm tan-yellow to pink fibroadipose tissue. Two lymph nodes are identified ranging in size from 0.5 to 2.5 cm in greatest dimension. The largest lymph node is serially sectioned into four parts and submitted entirely in cassette F1. The second lymph node is submitted in toto in cassette F2.

Part G. Received in formalin labeled "PELVIC IMPLANT" is a 3.0 x 1.5 x 0.6 cm tan-pink irregular rubbery piece of tissue which is serially sectioned and submitted entirely in two cassettes.

Pathology Resident
Microscopic Description
Performed.

The staff pathologist listed below has reviewed this case.

Pathology Resident
Electronically Signed Out

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order

- Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date

Order Time

[page 4 of 4]
Result Information

Result Date and Time

Status
Final resultPriority
Routine**Received Date/Time**

Received Date

Received Time

Order Providers

Authorizing Provider

Encounter Provider
None**Encounter**[View Encounter](#)**Reviewed by List****Order****SURGICAL PATHOLOGY****Administration Details**No Administrations
Recorded**Order Information**

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Order DetailsFrequency
ONCEDuration
1 occurrencePriority
RoutineOrder Class
Normal**Quantity**Ordering Quantity
1**Comments**

Ordered by

Original Order

Ordered On

Ordered By

Transfer Service**Collection Information**

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Authorizing Provider

Attending Provider(s)

Admitting Provider

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection**

** None **

Source: NCI Genomic Data Commons file 34c79fd5-8bd5-467e-a672-0db833824759 (TCGA-JV-A75J.7574F90B-32EC-440D-A74F-98AECDC43130.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).